Somatic mutation profile of tumor specimen PCProject_0254_T1_WES (aliquot PCProject_0254_T1_WES_1) from CMI case PCProject_0254, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 69.3 years (25,327 days).
Specimen PCProject_0254_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60bcb99d-25a7-4c9c-b5d8-ef1c15694434.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0254_SALIVA (Saliva), aliquot PCProject_0254_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5ff0917a-990c-4dc6-b637-28cf71b2a0bd

The open-access MAF lists 48 somatic variants for this specimen: 34 protein-altering or splice-affecting, 6 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 6, Intron 3, Frame Shift Del 2, 5'UTR 2, RNA 2, Splice Site 2, In Frame Ins 1, Nonstop Mutation 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXA1 | c.749C>T p.S250F | Missense Mutation (SNP) | VAF 38/105 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51644535, COSV51645490, COSV99032088; called by muse, mutect2, varscan2
- AKNA | c.3145G>A p.A1049T | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.537); catalogued as rs571164651, COSV56337417, COSV99799467; called by muse, mutect2, varscan2
- CCDC188 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.737); catalogued as rs1225677236; called by muse, mutect2, varscan2
- CCDC8 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 58/330 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1450940306; called by muse, mutect2, varscan2
- GPR161 | c.100A>G p.I34V | Missense Mutation (SNP) | VAF 97/403 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs1361561194; called by muse, mutect2, varscan2
- GTF2IRD1 | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs782351030; called by muse, mutect2, varscan2
- NCOR2 | c.655A>T p.I219F | Missense Mutation (SNP) | VAF 42/205 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs752679309; called by muse, mutect2, varscan2
- NYAP2 | c.1132del p.A378Rfs*69 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as COSV99797077; called by mutect2, pindel, varscan2
- TEX14 | c.577C>G p.R193G | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as COSV53616126; called by muse, mutect2, varscan2
- TMEM123 | c.517A>T p.I173F | Missense Mutation (SNP) | VAF 46/292 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371335707; called by muse, mutect2, varscan2
- XIRP1 | c.3697C>T p.R1233C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs761771175; called by muse, mutect2, varscan2
- ACAP3 | c.895G>T p.V299F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by mutect2, varscan2
- APOB | c.7432G>A p.A2478T | Missense Mutation (SNP) | VAF 60/295 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CDC45 | c.737A>T p.Q246L | Missense Mutation (SNP) | VAF 86/377 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- CRY1 | c.1589G>T p.C530F | Missense Mutation (SNP) | VAF 31/218 reads (14%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- DESI2 | c.34T>A p.Y12N | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- ELP2 | c.1874A>G p.N625S | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- GBP7 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- H2BC7 | c.380A>T p.*127Lext*2 | Nonstop Mutation (SNP) | VAF 42/330 reads (13%) | called by muse, mutect2
- HDAC6 | c.1000-1G>A p.X334_splice | Splice Site (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- HNRNPH3 | c.844A>G p.M282V | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.049); called by muse, mutect2
- HPS5 | c.1180A>G p.T394A (on ENST00000349215 / NM_181507.2; = p.T280A on NM_007216.4) | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- KDM8 | c.1241G>C p.W414S | Missense Mutation (SNP) | VAF 79/543 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRDE2 | c.2663A>G p.D888G | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- PELI2 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- PRDM10 | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RBM42 | c.1030dup p.L344Pfs*3 | Frame Shift Ins (INS) | VAF 15/121 reads (12%) | called by mutect2, pindel, varscan2
- SMC3 | c.80A>T p.H27L | Missense Mutation (SNP) | VAF 45/464 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SYNE2 | c.2373A>T p.L791F | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TOPBP1 | c.1071_1073dup p.D357_L358insF | In Frame Ins (INS) | VAF 48/363 reads (13%) | called by mutect2, pindel, varscan2
- TP53 | c.443_444del p.D148Vfs*32 | Frame Shift Del (DEL) | VAF 41/174 reads (24%) | called by mutect2, pindel, varscan2
- UBR5 | c.6630+2T>G p.X2210_splice | Splice Site (SNP) | VAF 51/180 reads (28%) | called by muse, mutect2, varscan2
- VIP | c.316C>G p.L106V | Missense Mutation (SNP) | VAF 50/297 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- WDR33 | c.3224G>T p.G1075V | Missense Mutation (SNP) | VAF 51/222 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C16orf96 | c.3201C>A p.I1067= | Silent (SNP) | VAF 31/251 reads (12%) | called by muse, mutect2, varscan2
- DCHS2 | c.588C>T p.A196= | Silent (SNP) | VAF 24/157 reads (15%) | catalogued as rs1367408282; called by muse, mutect2, varscan2
- GRK7 | c.186G>A p.Q62= | Silent (SNP) | VAF 73/306 reads (24%) | called by muse, mutect2, varscan2
- IGSF11 | c.606C>T p.I202= (on ENST00000393775 / NM_001015887.3; = p.I201= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/241 reads (16%) | called by muse, mutect2, varscan2
- PDE10A | c.1125G>C p.R375= | Silent (SNP) | VAF 92/351 reads (26%) | catalogued as COSV100604955, COSV63050211; called by muse, mutect2, varscan2
- TOM1L2 | c.1002G>T p.G334= (on ENST00000379504 / NM_001350333.2; = p.G284= on NM_001033551.3) | Silent (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- AC008060.1 | n.159T>C | RNA (SNP) | VAF 34/183 reads (19%) | called by muse, mutect2, varscan2
- ALKBH6 | c.-110C>G | 5'UTR (SNP) | VAF 48/295 reads (16%) | called by muse, mutect2, varscan2
- CRYGS | c.-3A>C | 5'UTR (SNP) | VAF 92/616 reads (15%) | called by muse, mutect2, varscan2
- HOXA2 | c.392-302T>G | Intron (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- LINC02691 | n.1414C>T | RNA (SNP) | VAF 57/239 reads (24%) | called by muse, mutect2, varscan2
- SELENOH | c.122+33A>G | Intron (SNP) | VAF 45/192 reads (23%) | called by muse, mutect2, varscan2
- SET | c.*1A>G | 3'UTR (SNP) | VAF 10/273 reads (4%) | called by muse, mutect2
- UROD | c.876-41T>C | Intron (SNP) | VAF 78/392 reads (20%) | catalogued as rs537467364; called by muse, mutect2, varscan2
